MMRF case MMRF_2089 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/6357d58b-499d-48ac-9195-d42d49fba16c

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 66 years; Vital status: Dead; Days to death: 449 days (1.2 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 66.9 years (24,417 days); ISS stage: III; Days to last known disease status: 449 days (1.2 years); Days to last follow up: 449 days (1.2 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 274 days.
   Treatment given: Therapeutic agents: Melphalan + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 253 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 295 days; Days to treatment end: 449 days (1.2 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 449.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -8 (ECOG 1): M Protein 3.49 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3416 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 7.34 mg/dL; Immunoglobulin G 47.4 g/L; Immunoglobulin A 0.259 g/L; Immunoglobulin M 0.173 g/L; Beta 2 Microglobulin 7.11 µg/mL; Lactate Dehydrogenase 4.58 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 6.31 ×10⁹/L; Absolute Neutrophil 3.05 ×10⁹/L; Platelets 103 ×10⁹/L; Creatinine 71.6 µmol/L; Calcium 2.53 mmol/L; Albumin 42 g/L; Total Protein 10.4 g/dL; Glucose 4.73 mmol/L.
- Day 85 (ECOG 0): M Protein 0.27 g/dL; Immunoglobulin G 9.28 g/L; Immunoglobulin A 0.185 g/L; Immunoglobulin M 0.212 g/L; Lactate Dehydrogenase 4.3 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 3.45 ×10⁹/L; Absolute Neutrophil 2.19 ×10⁹/L; Platelets 122 ×10⁹/L; Creatinine 66.3 µmol/L; Calcium 2.4 mmol/L; Albumin 44 g/L; Total Protein 6.9 g/dL; Glucose 4.62 mmol/L.
- Day 169 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.822 mg/dL; Immunoglobulin G 7.93 g/L; Immunoglobulin A 0.241 g/L; Immunoglobulin M 0.209 g/L; Lactate Dehydrogenase 4.27 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 93.6 ×10⁹/L; Creatinine 77.8 µmol/L; Calcium 2.35 mmol/L; Albumin 45 g/L; Total Protein 7.2 g/dL; Glucose 4.51 mmol/L.
- Day 253 (ECOG 1): M Protein 0.62 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 15.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.11 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 0.237 g/L; Immunoglobulin M 0.309 g/L; Lactate Dehydrogenase 3.47 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 2.52 ×10⁹/L; Absolute Neutrophil 1.97 ×10⁹/L; Platelets 48 ×10⁹/L; Creatinine 69 µmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 4.79 mmol/L.
- Day 351 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.45 mg/dL; Immunoglobulin G 7.99 g/L; Immunoglobulin A 0.345 g/L; Immunoglobulin M 0.383 g/L; Lactate Dehydrogenase 4.28 µkat/L; Hemoglobin 5.83 mmol/L; Leukocytes 1.58 ×10⁹/L; Absolute Neutrophil 0.75 ×10⁹/L; Platelets 58.3 ×10⁹/L; Creatinine 61.9 µmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 5.9 g/dL; Glucose 4.18 mmol/L.

Other clinical attributes
- Day -8: Weight: 62 kg; Height: 152 cm.

Family history
- Relative with cancer history: no.

Biospecimens (5 samples)
- Sample MMRF_2089_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -8 days.
- Sample MMRF_2089_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -8 days.
- Sample MMRF_2089_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 253 days.
- Sample MMRF_2089_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 449 days (1.2 years).
- Sample MMRF_2089_3_PB_CD138pos: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Days to sample procurement: 449 days (1.2 years).
